Gene-level copy-number profile of tumor specimen TCGA-EY-A4KR-01A from TCGA case TCGA-EY-A4KR, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC1; Tumor grade: G3; Age at diagnosis: 56.6 years (20,669 days).
Specimen TCGA-EY-A4KR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.78c85b81-6dfd-4151-a9cd-b81e569c9ec1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EY-A4KR-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d23d155c-d66a-4710-91d1-95fbae9b9e43

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 20,741; copy number 2: 33,491; copy number 3: 4,629; copy number 4: 718; copy number 5: 51; copy number 6: 98; copy number 7: 25; copy number 8: 57.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EY-A4KR-01A-11D-A27O-01): tumor purity 0.63, ploidy 2.01, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 231 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:202,028,606–202,096,978, 4 genes, copy number 5: AL691482.1, AL691482.2, Y_RNA, CRIP1P3.
- chr3:173,396,284–174,286,644, 1 gene, copy number 5 (within-gene range 3–5): NLGN1.
- chr3:173,910,498–174,378,005, 4 genes, copy number 5: NLGN1-AS1, RN7SKP234, ANAPC15P2, AC069218.1.
- chr3:174,631,823–174,632,064, 1 gene, copy number 5: RN7SKP40.
- chr8:126,552,443–128,564,679, 31 genes, copy number 5: LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, AC100822.1, LINC00824.
- chr12:47,661,249–48,106,079, 28 genes, copy number 6: RPAP3, AC004241.3, AC004241.1, ENDOU, AC004241.5, AC004241.2, RAPGEF3, SLC48A1, AC004241.4, HDAC7, AC004466.1, AC004466.3, AC004466.2, LINC02354, VDR, AC121338.1, AC121338.2, AC004801.7, TMEM106C, COL2A1, AC004801.5, AC004801.4, AC004801.3, AC004801.6, SENP1, AC004801.2, RNU6-1203P, AC004801.1.
- chr17:68,095,068–68,797,822, 26 genes, copy number 6: FBXO36P1, AC145343.1, LINC00674, LRRC37A16P, AC005332.6, AC005332.3, AC005332.5, SH3GL1P3, RDM1P3, AC005332.7, AC005332.2, ARHGAP27P2, AC005332.4, AMZ2, AC005332.1, ARSG, SLC16A6, AC007780.1, WIPI1, MIR635, PRKAR1A, FAM20A, AC079210.1, LINC01482, AC011591.2, AC011591.1.
- chr19:9,959,561–10,587,315, 44 genes, copy number 6: COL5A3, AC008742.1, RDH8, C3P1, MIR5589, SHFL, AC020931.1, ANGPTL6, PPAN-P2RY11, PPAN, SNORD105, SNORD105B, P2RY11, EIF3G, DNMT1, S1PR2, MIR4322, MRPL4, AC011511.2, AC011511.3, ICAM1, AC011511.5, ICAM4, ICAM5, ZGLP1, AC011511.1, FDX2, AC011511.4, RAVER1, AC114271.1, ICAM3, TYK2, CDC37, MIR1181, PDE4A, KEAP1, AC011461.1, S1PR5, ATG4D, RNU7-140P, MIR1238, KRI1, CDKN2D, AP1M2.
- chr19:27,638,483–30,872,507, 67 genes, copy number 5–8 (broad region; genes not listed).
- chr19:57,746,815–58,086,310, 25 genes, copy number 7: ZNF776, ZNF586, ZNF552, AC010522.1, ZNF587B, FKBP1AP1, ZNF814, ZNF587, AC010326.3, AC010326.4, AC010326.2, ZNF417, ZNF418, ZNF256, AC010326.1, C19orf18, ZNF606, AC008969.1, VN2R19P, AC008969.2, ZSCAN1, LETM1P2, HNRNPDLP4, ZNF135, RN7SL526P.

Autosomal genes at a single copy (total copy number 1): 19,894. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
